Somatic mutation profile of tumor specimen TCGA-A5-A0GN-01A (aliquot TCGA-A5-A0GN-01A-11W-A062-09) from TCGA case TCGA-A5-A0GN, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G1; Age at diagnosis: 65.8 years (24,020 days).
Specimen TCGA-A5-A0GN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f46a3ed5-40f8-4f60-ba9f-64d3ba40c078.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A5-A0GN-10A (Blood Derived Normal), aliquot TCGA-A5-A0GN-10A-01W-A062-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5be7b7ee-914a-46ae-8f1d-b0fbe48a601a

The open-access MAF lists 62 somatic variants for this specimen: 50 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 10, 3'UTR 2, Frame Shift Ins 2, In Frame Del 1, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.100G>A p.G34R | Missense Mutation (SNP) | VAF 33/98 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913399, COSV62687911, COSV62687931, COSV62721471; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DICER1 | c.4031C>T p.S1344L | Missense Mutation (SNP) | VAF 49/82 reads (60%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV58615689; called by muse, mutect2, varscan2
- ESR1 | c.1610A>G p.Y537C | Missense Mutation (SNP) | VAF 25/60 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV52782924, COSV52783938; called by muse, mutect2, varscan2
- KCNQ2 | c.430C>T p.R144W | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555873985, COSV60432857; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1637A>C p.Q546P | Missense Mutation (SNP) | VAF 44/87 reads (51%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs397517201, COSV55875400, COSV55876869, COSV55877455; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AASDHPPT | c.590G>C p.R197P | Missense Mutation (SNP) | VAF 50/150 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV53788688; called by muse, mutect2, varscan2
- ABCA4 | c.320G>A p.R107Q | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs759799179, COSV64671069, COSV64671123; called by muse, mutect2, varscan2
- ABTB2 | c.2119G>A p.V707M | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.311); catalogued as rs142325682; called by muse, mutect2, varscan2
- AHCTF1 | c.5773G>A p.D1925N (on ENST00000366508; = p.D1899N on NM_015446.5) | Missense Mutation (SNP) | VAF 67/421 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as COSV58247965; called by muse, mutect2, varscan2
- ANGPTL2 | c.626C>T p.S209L | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV52219303; called by muse, varscan2
- ANO1 | c.832G>C p.A278P | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.058); catalogued as COSV60282850, COSV60284696; called by muse, mutect2, varscan2
- AP3B1 | c.1450G>T p.A484S | Missense Mutation (SNP) | VAF 8/252 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.326); catalogued as COSV54880792; called by muse, mutect2
- BPTF | c.5694G>C p.Q1898H | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58833749, COSV58834539; called by muse, mutect2, varscan2
- CDH8 | c.1628C>T p.P543L | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.838); catalogued as rs1402685619, COSV54857975; called by muse, mutect2, varscan2
- CDKAL1 | c.1567G>C p.G523R | Missense Mutation (SNP) | VAF 53/126 reads (42%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs776660547, COSV51181545, COSV51182106; called by muse, mutect2, varscan2
- CFAP44 | c.1800C>G p.F600L | Missense Mutation (SNP) | VAF 52/214 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55610231; called by muse, mutect2, varscan2
- CTNNA2 | c.2279G>C p.R760P | Missense Mutation (SNP) | VAF 39/200 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV58135759, COSV58143869; called by muse, mutect2, varscan2
- DDX60 | c.2306G>A p.R769Q | Missense Mutation (SNP) | VAF 55/151 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.463); catalogued as rs1308760097, COSV67095816; called by muse, mutect2, varscan2
- DOCK2 | c.844-1G>A p.X282_splice | Splice Site (SNP) | VAF 72/282 reads (26%) | catalogued as COSV56951043; called by muse, mutect2, varscan2
- DSC2 | c.1663G>C p.G555R | Missense Mutation (SNP) | VAF 9/233 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.058); catalogued as COSV51862645, COSV99199894; called by muse, mutect2
- DSEL | c.104C>G p.S35C | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.878); catalogued as COSV59490428, COSV59494682; called by muse, mutect2, varscan2
- EHF | c.844C>G p.R282G | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57667909, COSV99140856; called by muse, mutect2, varscan2
- ERC1 | c.2485C>T p.Q829* (on ENST00000360905 / NM_178040.4; = p.Q801* on NM_178039.4) | Nonsense Mutation (SNP) | VAF 57/172 reads (33%) | catalogued as COSV61693220; called by muse, mutect2, varscan2
- FAT1 | c.9358G>A p.D3120N | Missense Mutation (SNP) | VAF 70/206 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.116); catalogued as rs746965574, COSV71673024, COSV71674326; called by muse, mutect2
- FCGBP | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 87/111 reads (78%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.757); catalogued as rs1297465608; called by muse, mutect2, varscan2
- FLAD1 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 28/38 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52695918, COSV52696358, COSV99422625; called by muse, mutect2, varscan2
- FZD3 | c.1054A>T p.I352F | Missense Mutation (SNP) | VAF 88/317 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53534880; called by muse, mutect2, varscan2
- GIGYF2 | c.3779G>T p.S1260I | Missense Mutation (SNP) | VAF 34/187 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV65247938; called by muse, mutect2, varscan2
- GLOD4 | c.397G>A p.E133K (on ENST00000301328 / NM_001366247.1; = p.E118K on NM_016080.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 121/326 reads (37%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs768237197, COSV56753021; called by muse, mutect2, varscan2
- GPRC6A | c.1940C>T p.T647M | Missense Mutation (SNP) | VAF 16/271 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs896498354, COSV59952307, COSV59954340; called by muse, mutect2
- HINT3 | c.284A>G p.N95S | Missense Mutation (SNP) | VAF 72/239 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.31); catalogued as COSV57649566; called by muse, mutect2, varscan2
- IGLV8-61 | c.149C>T p.S50F | Missense Mutation (SNP) | VAF 51/146 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs966368534, COSV66502603; called by muse, mutect2, varscan2
- KCNJ5 | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs142140011; called by muse, mutect2, varscan2
- NEUROD1 | c.431G>T p.R144L | Missense Mutation (SNP) | VAF 42/223 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54548631, COSV54549328; called by muse, mutect2, varscan2
- NPY5R | c.322A>G p.M108V | Missense Mutation (SNP) | VAF 102/286 reads (36%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1300454687, COSV58451439; called by muse, mutect2, varscan2
- OVCH1 | c.1456G>C p.E486Q | Missense Mutation (SNP) | VAF 205/401 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.839); catalogued as COSV58961245; called by muse, mutect2, varscan2
- SLC12A1 | c.606G>C p.W202C | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM088248, COSV57708814; called by muse, mutect2
- SLC39A10 | c.2232A>G p.I744M | Missense Mutation (SNP) | VAF 18/695 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as COSV62766787; called by muse, mutect2
- SORL1 | c.1786G>A p.V596I | Missense Mutation (SNP) | VAF 55/163 reads (34%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs1267522196, COSV52751859; called by muse, mutect2, varscan2
- SREBF2 | c.2686C>T p.R896C | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as rs760768724, COSV63330819; called by muse, mutect2
- STK38 | c.887A>T p.Q296L | Missense Mutation (SNP) | VAF 66/194 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.955); catalogued as COSV57708124; called by muse, mutect2, varscan2
- TAF9B | c.619G>A p.V207I | Missense Mutation (SNP) | VAF 16/187 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.785); catalogued as COSV59371046; called by muse, mutect2
- TCEAL3 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.737); catalogued as rs1172849872, COSV54580370; called by muse, mutect2
- TMEM215 | c.250C>T p.R84W | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV61363293; called by muse, mutect2
- TNS1 | c.2471C>T p.P824L | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs567400983, COSV50694258; called by muse, mutect2, varscan2
- TRPA1 | c.3126G>A p.M1042I | Missense Mutation (SNP) | VAF 65/263 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV51555812, COSV51558488; called by muse, mutect2, varscan2
- TTC30A | c.1490G>C p.S497T | Missense Mutation (SNP) | VAF 66/389 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.022); catalogued as COSV63101032; called by muse, mutect2, varscan2
- MBD4 | c.1532_1534del p.L511del | In Frame Del (DEL) | VAF 28/96 reads (29%) | called by mutect2, pindel, varscan2
- MORC4 | c.1119dup p.Y374Lfs*7 | Frame Shift Ins (INS) | VAF 102/200 reads (51%) | called by mutect2, pindel, varscan2
- VPS13C | c.671_672dup p.L225Sfs*5 (on ENST00000644861 / NM_020821.3; = p.L182Sfs*5 on NM_017684.5) | Frame Shift Ins (INS) | VAF 37/123 reads (30%) | called by mutect2, pindel, varscan2
- AGPS | c.1779C>T p.T593= | Silent (SNP) | VAF 132/224 reads (59%) | catalogued as rs753841033, COSV51561750; called by muse, mutect2, varscan2
- AMOTL2 | c.1692C>T p.A564= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as rs758990000, COSV51438420, COSV99850664; called by muse, mutect2, varscan2
- ANAPC1 | c.675T>C p.C225= | Silent (SNP) | VAF 32/185 reads (17%) | catalogued as COSV61975183; called by muse, mutect2, varscan2
- B4GALNT3 | c.2910C>T p.D970= | Silent (SNP) | VAF 16/31 reads (52%) | catalogued as rs774334939, COSV56751294; called by muse, mutect2, varscan2
- BTN2A1 | c.1275G>A p.E425= | Silent (SNP) | VAF 56/165 reads (34%) | catalogued as rs779754802, COSV57002785; called by muse, mutect2, varscan2
- CCKBR | c.615C>T p.C205= | Silent (SNP) | VAF 49/124 reads (40%) | catalogued as rs1430271577, COSV58100024; called by muse, mutect2, varscan2
- FHOD3 | c.2634C>T p.S878= (on ENST00000359247 / NM_001281739.3; = p.S895= on NM_025135.5) | Silent (SNP) | VAF 122/300 reads (41%) | catalogued as rs1310731572, COSV57169197; called by muse, mutect2, varscan2
- LRFN2 | c.915G>A p.A305= | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as rs779512124, COSV57825552; called by muse, mutect2, varscan2
- LRP1B | c.10470C>T p.P3490= | Silent (SNP) | VAF 51/245 reads (21%) | catalogued as rs752743011, COSV67201447; called by muse, mutect2, varscan2
- MKI67 | c.6996G>T p.T2332= | Silent (SNP) | VAF 138/610 reads (23%) | catalogued as rs773080435, COSV100896277, COSV64073544; called by muse, mutect2, varscan2
- C16orf89 | c.*187A>T | 3'UTR (SNP) | VAF 19/53 reads (36%) | catalogued as COSV60122980; called by muse, mutect2, varscan2
- CD80 | c.*2A>T | 3'UTR (SNP) | VAF 41/167 reads (25%) | catalogued as COSV99956200; called by muse, mutect2, varscan2
